Somatic mutation profile of tumor specimen 0DH9L9 from CCDI case PBBUBR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Vagina, NOS; Age at diagnosis: 1.7 years (604 days).
Specimen 0DH9L9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 059f1eab-8895-4ca0-801b-c44ab3832c82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH9L0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/669cf68b-9a3a-458a-93b8-1123b1197b58

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 5'UTR 2, Intron 1, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF6 | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 321/1202 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs775294304, COSV54688617; called by muse, mutect2, varscan2
- TMC7 | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 216/903 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs760514749, COSV58587295; called by muse, mutect2, varscan2
- TTC25 | c.1145+1G>A p.X382_splice | Splice Site (SNP) | VAF 25/695 reads (4%) | catalogued as rs189239015, COSV66368317; called by muse, mutect2
- UNK | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 77/517 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1384977462; called by muse, mutect2, varscan2
- CFAP54 | c.8040G>T p.K2680N | Missense Mutation (SNP) | VAF 153/799 reads (19%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- GPR158 | c.3325G>C p.A1109P | Missense Mutation (SNP) | VAF 40/1433 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.143); called by muse, mutect2
- OR56A1 | c.708G>A p.A236= | Silent (SNP) | VAF 252/990 reads (25%) | catalogued as rs780178315, COSV100360509; called by muse, mutect2, varscan2
- ABLIM3 | c.-71G>C | 5'UTR (SNP) | VAF 50/468 reads (11%) | catalogued as COSV100448869; called by muse, mutect2, varscan2
- RETNLB | c.-48C>A | 5'UTR (SNP) | VAF 50/660 reads (8%) | called by muse, mutect2
- SEC61G | c.197+48C>A | Intron (SNP) | VAF 122/551 reads (22%) | called by muse, mutect2, varscan2
